Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A266, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A266-06A (Metastatic).

1CD-0-3

Melanoma, malignant, NOS 8720/3

Site: neck, NOS C44.4

hw
4/27/11

SPECIMENS:

- A. TEETH
- B. RESECTION LT POSTEROR NECK

DIAGNOSIS:

- A. TEETH:
- SEE GROSS DESCRIPTION.
- B. RESECTION, METASTATIC MELANOMA, LEFT POSTERIOR NECK, INCLUDING TRAPEZIUS MUSCLE AND POSTERIOR TRIANGLE SELECTIVE DISSECTION:
- CONSISTENT WITH METASTATIC MALIGNANT MELANOMA (3.5 X 3.2 C 2.5 CM) see note
- SIZE OF TUMOR 3.5 X 3.2 X 2.5 CM.

note:

Tumor seen involving deeper dermis subcutaneous adipose and muscle tissue. epidermis shows no evidence of junctional nesting. Tumor in areas with malignant fibrous histiocytoma like pattern features..Tumor seen 0.5 mm from nearest deep margin.
Immunostains show strong positive immunoreactivity for S100., focal non-specific positive staining for microphthalmia.
- rare tumor consistent with faint weak staining for hmb45.
- negative immunoreactivity for sma, desmin, cd68, a10.

Slides also revealed by Dr.
See also path report #.

SPECIMEN(S):

- A. TEETH B. RESECTION LT POSTEROR NECK

GROSS DESCRIPTION:

- A. TEETH:

Received in formalin with matching patient name and requisition number are four molar and four incisor teeth measuring in aggregate 4x3x0.5 cm. with caries and no attached soft tissue. Gross only. No tissue is submitted.
- B. RESECTION METASTATIC MELANOMA LEFT POSTERIOR NECK INCLUDING TRAPEZIUS MUSCLE AND POSTERIOR TRIANGLE SELECTIVE DISSECTION:

Received in formalin in a container with matching patient name and requisition number is a 8x4x0.2 cm ellipse of skin with a linear well healed scar in its center measuring 4.5 cm. in length and no other focal lesions on its surface. With an underlying 10x4x2.7 cm. soft tissue containing a well circumscribed white firm lesion measuring 3.5x3.2x2.5 cm. within 0.1 cm. of the deep and the inferior (green) margin. The superior margin is inked yellow. There are no other focal lesions noted. Representatives of the lesion with the skin, superior, inferior, deep margins are submitted in B1 to B4.

Gross Dictation: Pathology Resident,
Microscopic/Diagnostic Dictation: Pathologist,
Microscopic/Diagnostic Dictation: Pathologist,
Final Review: Pathologist,
Final: Pathologist,

Source: NCI Genomic Data Commons file 347cabc2-ea5e-46f7-b9ee-e3382f120e47 (TCGA-GN-A266.0E9DDC94-6AC6-44D2-AE57-DEF276F10CB2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).